Somatic mutation profile of tumor specimen MP2PRT-PARCYM-TMP1-A (aliquot MP2PRT-PARCYM-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARCYM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (888 days).
Specimen MP2PRT-PARCYM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0143e9c4-5651-4082-b743-b1b919442d08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARCYM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARCYM-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c151c89-3032-4797-9d47-4a43b67d58c6

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4349A>G p.Y1450C | Missense Mutation (SNP) | VAF 48/263 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52119179, COSV52130109; called by muse, mutect2, varscan2
- FLT3 | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1057520022, COSV54065509, COSV54077224; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DGKK | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1557223896, COSV101053261; called by muse, mutect2, varscan2
- MAPKBP1 | c.904G>A p.V302M (on ENST00000456763 / NM_001128608.2; = p.V296M on NM_014994.3) | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1451298981; called by muse, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 30/483 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2
- SEMA5A | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374411686; called by muse, mutect2, varscan2
- SORCS2 | c.3451C>T p.R1151* | Nonsense Mutation (SNP) | VAF 68/391 reads (17%) | catalogued as rs200114314, COSV100214152; called by muse, mutect2, varscan2
- MLLT6 | c.884G>T p.S295I | Missense Mutation (SNP) | VAF 51/515 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- NID1 | c.3224G>A p.R1075K | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TXNDC5 | c.773A>G p.Q258R | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2
- ZNF365 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 55/434 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FHL2 | chr2:105399288 C>T | 5'Flank (SNP) | VAF 26/362 reads (7%) | called by muse, mutect2
